FM case AD15259 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/a5ff5d18-6f8f-47f7-9d36-eac567331ed4

Female, 79.7 years: Melanoma, NOS (ICD-O-3 8720/3) of the head, face or neck. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
